Somatic mutation profile of tumor specimen TCGA-E6-A1LZ-01A (aliquot TCGA-E6-A1LZ-01A-11D-A142-09) from TCGA case TCGA-E6-A1LZ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 76.8 years (28,054 days).
Specimen TCGA-E6-A1LZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43c6fc09-a3a7-4ae7-ad8f-1662dc9a832d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E6-A1LZ-10A (Blood Derived Normal), aliquot TCGA-E6-A1LZ-10A-01D-A142-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ae7f4d2-f08b-4617-98f8-9f2fcf3480b0

The open-access MAF lists 262 somatic variants for this specimen: 202 protein-altering or splice-affecting, 58 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 171, Silent 58, Nonsense Mutation 23, Frame Shift Del 4, RNA 2, Splice Region 2, Nonstop Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 17/194 reads (9%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: likely pathogenic; called by muse, mutect2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 24/117 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ABCA4 | c.796C>G p.Q266E | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs764368214, COSV64670536; called by muse, mutect2, varscan2
- ABHD1 | c.878C>G p.S293C | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1466678507, COSV53204263; called by muse, mutect2, varscan2
- ACOT6 | c.64G>C p.D22H | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66968735; called by muse, mutect2, varscan2
- ACTR1B | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV56703004; called by muse, mutect2, varscan2
- ADGRG4 | c.4188G>C p.M1396I | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV54948399; called by muse, mutect2, varscan2
- AGPAT5 | c.679G>C p.D227H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53445355; called by muse, mutect2, varscan2
- AGTR1 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763952495, COSV62557123; called by muse, mutect2, varscan2
- AHNAK2 | c.2492G>C p.S831T | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as rs776666854, COSV60906388; called by muse, mutect2, varscan2
- AHNAK2 | c.1624G>C p.E542Q | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.052); catalogued as COSV60906395, COSV60909645; called by muse, mutect2, varscan2
- ALMS1 | c.4715C>G p.S1572* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as CM156231, COSV52501323; called by muse, mutect2
- ALMS1 | c.12152G>T p.R4051L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV52501334, COSV52512355; called by muse, mutect2, varscan2
- ALS2 | c.2938G>C p.E980Q | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51883563, COSV99969206; called by muse, mutect2
- ANKRD12 | c.5489C>T p.S1830L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV50818990; called by muse, mutect2
- ANKRD50 | c.4006C>T p.Q1336* | Nonsense Mutation (SNP) | VAF 15/96 reads (16%) | catalogued as COSV101538894, COSV72384969; called by muse, mutect2, varscan2
- AP1M2 | c.180C>G p.I60M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV51565220, COSV51566236; called by muse, mutect2, varscan2
- APOA5 | c.1057C>G p.H353D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as COSV57062065, COSV57064138; called by muse, mutect2, varscan2
- AQR | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50029377; called by muse, mutect2, varscan2
- ARHGAP35 | c.226T>A p.W76R | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68328912; called by muse, mutect2, varscan2
- ARHGAP5 | c.3856G>A p.E1286K (on ENST00000345122 / NM_001030055.2; = p.E1285K on NM_001173.3) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61533589; called by muse, mutect2
- ATP2C1 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 14/107 reads (13%) | catalogued as COSV60752033; called by muse, mutect2, varscan2
- C11orf16 | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV58166280; called by muse, mutect2, varscan2
- C22orf23 | c.69C>G p.I23M | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as COSV50777609; called by muse, mutect2, varscan2
- C4orf17 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.164); catalogued as rs1164869396, COSV58511134, COSV58513402; called by muse, mutect2, varscan2
- CA14 | c.218G>C p.G73A | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.144); catalogued as COSV64257144; called by muse, mutect2, varscan2
- CACNA1F | c.2710C>G p.L904V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59902776; called by muse, mutect2, varscan2
- CATSPER1 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.14); catalogued as rs543744984, COSV56408716; called by muse, mutect2, varscan2
- CCDC112 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV65472607; called by muse, mutect2, varscan2
- CCDC83 | c.1138A>T p.M380L (on ENST00000342404 / NM_001286159.2; = p.M411L on NM_173556.5) | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV54699381; called by muse, mutect2, varscan2
- CCNT1 | c.46C>G p.R16G | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs888184488, COSV56062944, COSV56065813; called by muse, mutect2
- CCSER1 | c.1567C>G p.L523V | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV61402593; called by muse, mutect2, varscan2
- CEP162 | c.1942G>C p.E648Q | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.93); catalogued as COSV57616834; called by muse, mutect2, varscan2
- CEP350 | c.242G>C p.R81T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as COSV62485607; called by muse, mutect2
- CIT | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV55858740; called by muse, mutect2, varscan2
- CNTN6 | c.3086G>C p.*1029Sext*1 | Nonstop Mutation (SNP) | VAF 6/104 reads (6%) | catalogued as COSV63160259; called by muse, mutect2
- COL5A3 | c.3341C>T p.P1114L | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.788); catalogued as rs750592534, COSV53405245; called by muse, mutect2, varscan2
- CPSF2 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV54096792; called by muse, mutect2, varscan2
- CRYBG1 | c.2757C>A p.N919K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV64810276; called by muse, mutect2
- CSE1L | c.2218T>C p.S740P | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53700217; called by muse, mutect2
- DCC | c.1045G>C p.E349Q | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as COSV100497852, COSV59080926, COSV59107578; called by muse, mutect2, varscan2
- DECR1 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.076); catalogued as COSV55166414; called by muse, mutect2, varscan2
- DLC1 | c.472C>G p.Q158E | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV52288328; called by muse, mutect2, varscan2
- DMD | c.3130G>C p.E1044Q | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.187); catalogued as COSV100821731, COSV63732339; called by muse, mutect2, varscan2
- DNAH3 | c.2392G>C p.E798Q | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs1286389645, COSV54500770; called by muse, mutect2, varscan2
- DOCK5 | c.3928A>T p.K1310* | Nonsense Mutation (SNP) | VAF 16/80 reads (20%) | catalogued as COSV52395268; called by muse, mutect2, varscan2
- DYRK2 | c.391C>T p.H131Y (on ENST00000344096 / NM_006482.3; = p.H58Y on NM_003583.4) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV59845099; called by muse, mutect2
- E2F2 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as rs1441798367, COSV62276188; called by muse, mutect2, varscan2
- EDNRA | c.1004A>T p.E335V | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as rs1394625720, COSV60095327; called by muse, mutect2, varscan2
- EMILIN2 | c.1172C>G p.S391* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as COSV54420409, COSV54421799; called by muse, mutect2, varscan2
- ENTPD6 | c.1286C>G p.S429* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV61750796; called by muse, mutect2, varscan2
- ERN2 | c.1476G>T p.K492N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.062); catalogued as COSV56831232; called by muse, mutect2, varscan2
- FAT4 | c.14171A>G p.H4724R | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); catalogued as rs1238833056, COSV58669617; called by muse, mutect2, varscan2
- FLG | c.10420G>C p.D3474H | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV64235579, COSV64247356; called by muse, mutect2
- FLG | c.9835G>A p.A3279T | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT tolerated (0.96); PolyPhen benign (0.037); catalogued as rs115482787, COSV64246012; called by muse, mutect2, varscan2
- FMNL1 | c.2667G>C p.E889D | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.102); catalogued as COSV58954864; called by muse, mutect2
- FMNL2 | c.675C>G p.I225M | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56489285; called by muse, mutect2
- FNTA | c.557T>G p.L186R | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV56489007; called by muse, mutect2, varscan2
- FOXN3 | c.658A>G p.T220A | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV54303390; called by muse, mutect2, varscan2
- FOXR2 | c.667C>G p.R223G | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV59257690; called by muse, mutect2
- GALNT3 | c.829G>C p.D277H | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67061326; called by muse, mutect2
- GJA1 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV56996771; called by muse, mutect2
- GLRA4 | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | catalogued as COSV65455009; called by muse, mutect2, varscan2
- GPAT2 | c.1891G>C p.E631Q | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV64002959; called by muse, mutect2, varscan2
- GRB10 | c.1348G>A p.E450K (on ENST00000398812; = p.E404K on NM_001001549.3) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV60006944; called by muse, varscan2
- GRK3 | c.634G>C p.D212H | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60792772; called by muse, mutect2, varscan2
- GRM8 | c.1027C>G p.R343G | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.421); catalogued as COSV58797870, COSV58823078; called by muse, mutect2, varscan2
- H4C13 | c.128G>A p.G43D | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV60693028; called by muse, mutect2, varscan2
- HDX | c.1472G>A p.R491K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52972283; called by muse, mutect2, varscan2
- HECTD4 | c.11491G>C p.E3831Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV66385988; called by muse, mutect2, varscan2
- HEPHL1 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV59889128; called by muse, mutect2
- HIF1A | c.357C>A p.Y119* | Nonsense Mutation (SNP) | VAF 9/122 reads (7%) | catalogued as COSV60187996; called by muse, mutect2
- HOXB3 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61142348; called by muse, mutect2
- IDH1 | c.274T>C p.W92R | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1048933669, COSV61615367, COSV61628453; called by muse, mutect2, varscan2
- IL18BP | c.484C>T p.H162Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1445018089, COSV52619517; called by muse, mutect2
- IPO11 | c.1509G>C p.W503C | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57571555; called by muse, mutect2, varscan2
- IPO7 | c.1636C>G p.L546V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63352491; called by muse, mutect2, varscan2
- IQGAP1 | c.2584G>C p.E862Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV51581127; called by muse, mutect2, varscan2
- ITGA8 | c.1999G>C p.E667Q | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100959558, COSV65223898; called by muse, mutect2, varscan2
- JMJD6 | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57969848; called by muse, mutect2, varscan2
- KCNN4 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); catalogued as COSV53454457, COSV99487121; called by muse, mutect2
- KIAA1109 | c.13942G>C p.D4648H | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.954); catalogued as COSV52660925, COSV52697357; called by muse, mutect2
- KMT2D | c.11372C>A p.S3791Y | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as COSV56407236; called by muse, mutect2, varscan2
- KRR1 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV56989530; called by muse, mutect2, varscan2
- KRT39 | c.1075G>C p.D359H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.076); catalogued as COSV62916777; called by muse, mutect2, varscan2
- KRT39 | c.991C>T p.R331* | Nonsense Mutation (SNP) | VAF 10/85 reads (12%) | catalogued as COSV62916783; called by muse, mutect2, varscan2
- KRTAP10-4 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs782450087, COSV59949971; called by muse, mutect2, varscan2
- LAMB1 | c.4912G>A p.E1638K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV55961166; called by muse, mutect2, varscan2
- LDHA | c.76G>C p.V26L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV57038426; called by muse, mutect2
- LGI3 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV60442817; called by muse, mutect2, varscan2
- LIPE | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.108); catalogued as COSV54920937; called by muse, mutect2, varscan2
- LMTK2 | c.3980G>T p.G1327V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs1349700685, COSV51989554; called by muse, mutect2, varscan2
- LRP1B | c.9818C>G p.S3273C | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV67181929; called by muse, mutect2
- LRP2 | c.8146G>C p.E2716Q | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV55538807; called by muse, mutect2
- LRRC43 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); catalogued as rs764289368, COSV60287836; called by muse, mutect2, varscan2
- LSG1 | c.1230G>C p.K410N | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54568239; called by muse, mutect2, varscan2
- MAGEB6 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 15/85 reads (18%) | catalogued as COSV66871752; called by muse, mutect2, varscan2
- MCCC1 | c.1094G>T p.G365V | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55605960; called by muse, mutect2
- MID1 | c.479G>C p.R160P | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV58191150; called by muse, mutect2, varscan2
- MOGAT3 | c.404C>G p.S135C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1455011151, COSV56172506; called by muse, mutect2, varscan2
- MORC3 | c.2687G>C p.R896P | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68687646; called by muse, mutect2, varscan2
- MTMR9 | c.1311T>G p.F437L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV55310197; called by muse, mutect2, varscan2
- MYCBP2 | c.12292G>A p.V4098M (on ENST00000357337; = p.V4136M on NM_015057.5) | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.123); catalogued as COSV62008827; called by muse, mutect2, varscan2
- MYH15 | c.4747G>A p.E1583K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV56303627; called by muse, mutect2, varscan2
- NCOA5 | c.1037T>C p.I346T | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV51642057; called by muse, mutect2, varscan2
- NEUROD6 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 32/186 reads (17%) | catalogued as COSV51769347, COSV51770836; called by muse, varscan2
- NFASC | c.725G>C p.R242T (on ENST00000339876 / NM_001378329.1; = p.R253T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.467); catalogued as rs374629132, COSV100366126; called by muse, mutect2, varscan2
- NIPBL | c.569C>G p.S190C | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV56940942; called by muse, mutect2, varscan2
- NUSAP1 | c.412G>C p.D138H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as rs189325557, COSV52969752; called by muse, mutect2, varscan2
- OR10R2 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63768378; called by muse, mutect2, varscan2
- OR11G2 | c.176G>C p.R59T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.258); catalogued as COSV62131630; called by muse, mutect2, varscan2
- OR4A16 | c.934T>C p.S312P | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.006); catalogued as rs760783441, COSV100125152, COSV59041708; called by mutect2, varscan2
- P2RX3 | c.255G>A p.Q85= | Splice Region (SNP) | VAF 7/31 reads (23%) | catalogued as COSV54441295; called by muse, mutect2, varscan2
- PARP14 | c.4232C>G p.S1411C | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.613); catalogued as COSV71734050; called by muse, mutect2, varscan2
- PAX8 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1289294447, COSV54506130; called by muse, mutect2, varscan2
- PCBP1 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV100340018, COSV57849597; called by muse, mutect2, varscan2
- PCDH15 | c.4885G>T p.E1629* | Nonsense Mutation (SNP) | VAF 30/125 reads (24%) | catalogued as COSV57256634; called by muse, mutect2, varscan2
- PCDHB7 | c.254T>C p.L85P | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as COSV50753495; called by muse, mutect2
- PCDHGA4 | c.2260C>G p.R754G | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.626); catalogued as COSV53892016, COSV99533134; called by muse, mutect2, varscan2
- PCLO | c.11041G>C p.D3681H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61612586, COSV61629919; called by muse, mutect2, varscan2
- PCNX1 | c.6818G>A p.G2273E | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.055); catalogued as rs753263653, COSV53088379; called by muse, mutect2, varscan2
- PDK3 | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV64792686; called by muse, mutect2, varscan2
- PEG3 | c.3643G>C p.E1215Q | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.97); PolyPhen benign (0.005); catalogued as rs1326935020, COSV55623249; called by muse, mutect2, varscan2
- PGAM4 | c.432C>A p.D144E | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV58441732, COSV58444631; called by muse, mutect2, varscan2
- PHC3 | c.551C>T p.P184L (on ENST00000494943 / NM_001308116.2; = p.P196L on NM_024947.4) | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63051402; called by muse, mutect2, varscan2
- PIK3CA | c.2975G>C p.R992P | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55873844, COSV55878461, COSV55906410; called by muse, mutect2, varscan2
- PLA2G6 | c.1410G>A p.M470I | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV59267640; called by muse, mutect2, varscan2
- PLCE1 | c.2056G>T p.E686* | Nonsense Mutation (SNP) | VAF 17/94 reads (18%) | catalogued as COSV53335171; called by muse, mutect2, varscan2
- PMS1 | c.1150G>C p.D384H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV59714402; called by muse, mutect2, varscan2
- PNMA8B | c.1437C>A p.Y479* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV66535599; called by muse, mutect2, varscan2
- POF1B | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.678); catalogued as rs796956414, COSV53129802, COSV99427567; called by muse, mutect2, varscan2
- PPFIA1 | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as rs759948657, COSV54131051; called by mutect2, varscan2
- PPIP5K2 | c.3672G>C p.K1224N (on ENST00000358359 / NM_001276277.3; = p.K1203N on NM_015216.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.034); catalogued as COSV58602095; called by muse, mutect2, varscan2
- PPP1R2 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.248); catalogued as COSV60496968; called by muse, mutect2
- PPP1R27 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.358); catalogued as COSV57672154; called by muse, mutect2, varscan2
- PSG2 | c.991C>G p.L331V | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV61544511, COSV61545043; called by muse, mutect2, varscan2
- PSG8 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 18/194 reads (9%) | catalogued as COSV100126610, COSV60609151; called by muse, mutect2
- PTPRD | c.4738G>C p.D1580H | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61925098, COSV61935788; called by muse, mutect2, varscan2
- PTPRK | c.155A>T p.Y52F | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.391); catalogued as COSV63890219; called by muse, mutect2, varscan2
- RBM10 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV61307540; called by muse, mutect2
- RBM26 | c.1262C>G p.S421C | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.846); catalogued as COSV57390720; called by muse, mutect2, varscan2
- RIMS2 | c.2314C>G p.L772V (on ENST00000666250 / NM_001348490.2; = p.L580V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51649502, COSV51695846; called by muse, mutect2, varscan2
- RNF20 | c.2335G>T p.E779* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as COSV66660174; called by muse, mutect2, varscan2
- RTP4 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 54/90 reads (60%) | SIFT tolerated (0.28); PolyPhen benign (0.053); catalogued as rs776702663, COSV52017981; called by muse, mutect2, varscan2
- RYR1 | c.14248G>A p.E4750K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV62087128; called by muse, mutect2
- SAMM50 | c.813C>G p.I271M | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63109266; called by muse, mutect2, varscan2
- SAXO1 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV65868270; called by muse, mutect2, varscan2
- SBF2 | c.2708G>C p.G903A | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV56290017; called by muse, mutect2, varscan2
- SENP1 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV50286543; called by muse, mutect2
- SEPTIN14 | c.972del p.N324Kfs*29 | Frame Shift Del (DEL) | VAF 10/79 reads (13%) | catalogued as COSV66425772; called by mutect2, varscan2
- SETD2 | c.4487G>A p.R1496Q | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1553699111, COSV57428732; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A45 | c.223G>C p.G75R | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53683146, COSV99587329; called by muse, mutect2, varscan2
- SLC28A1 | c.819C>G p.F273L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.311); catalogued as COSV54476040, COSV54487243; called by muse, mutect2, varscan2
- SLITRK2 | c.1416C>G p.N472K | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV59422595; called by muse, mutect2, varscan2
- SMARCAD1 | c.2461G>C p.D821H | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62772695; called by muse, mutect2, varscan2
- SOX6 | c.1221G>C p.K407N (on ENST00000528429 / NM_001145819.2; = p.K366N on NM_017508.3) | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs763877978, COSV57035488; called by muse, mutect2, varscan2
- SPG11 | c.1612G>T p.E538* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV55990230; called by muse, mutect2, varscan2
- STAG2 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV54349782; called by muse, mutect2, varscan2
- STK36 | c.662C>G p.S221* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as COSV55305625; called by muse, mutect2, varscan2
- STRAP | c.448C>G p.L150V | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.078); catalogued as rs1197060982, COSV50308175; called by muse, mutect2
- SUCO | c.3655C>G p.L1219V | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.957); catalogued as COSV55261379; called by muse, mutect2, varscan2
- SYTL5 | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV52897967; called by muse, mutect2, varscan2
- TAS2R46 | c.412C>A p.L138I | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV67851424; called by muse, mutect2, varscan2
- TECRL | c.418C>G p.Q140E | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV67085201; called by muse, mutect2, varscan2
- THSD7A | c.3559C>T p.R1187W | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs986010893, COSV69855313; called by muse, mutect2, varscan2
- TINAG | c.1080C>T p.N360= | Splice Region (SNP) | VAF 20/52 reads (38%) | catalogued as rs753282275, COSV52505001; called by muse, varscan2
- TNFRSF11B | c.525G>C p.Q175H | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV52069022, COSV52074058; called by muse, mutect2, varscan2
- TPR | c.5887G>C p.E1963Q | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.932); catalogued as COSV66599051, COSV66602432; called by muse, mutect2, varscan2
- TRIM28 | c.2090C>A p.S697* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV53398630; called by muse, mutect2, varscan2
- TRIM68 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV56167270; called by muse, mutect2
- TRIR | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.58); catalogued as COSV54406468; called by muse, mutect2, varscan2
- TRMT13 | c.1186G>C p.D396H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as COSV61582591; called by muse, mutect2
- TRO | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV51496985; called by muse, mutect2, varscan2
- TRO | c.2453G>T p.C818F | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs199679457, COSV51496999; called by muse, mutect2, varscan2
- TTC3 | c.2979C>G p.F993L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100696033, COSV61285136; called by muse, mutect2, varscan2
- TUB | c.918G>C p.K306N (on ENST00000299506 / NM_177972.3; = p.K361N on NM_003320.4) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100210099, COSV55106387; called by muse, mutect2
- TUBB8 | c.280C>G p.Q94E | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV59114449; called by muse, mutect2, varscan2
- UGT1A9 | c.364del p.S122Qfs*12 | Frame Shift Del (DEL) | VAF 19/159 reads (12%) | catalogued as rs773627969; called by mutect2, pindel, varscan2
- UNC13C | c.5116G>A p.E1706K | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.339); catalogued as rs1210051670, COSV52839668; called by muse, mutect2, varscan2
- USP54 | c.1115G>T p.S372I | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV60439288; called by muse, mutect2, varscan2
- USP6 | c.2419C>G p.P807A | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.123); catalogued as COSV51472840; called by muse, mutect2, varscan2
- YTHDF2 | c.337A>T p.S113C | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV65722513; called by muse, mutect2, varscan2
- ZBTB47 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1371762694, COSV51763304; called by muse, mutect2, varscan2
- ZC3H12B | c.307G>C p.D103H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV59045989; called by muse, mutect2, varscan2
- ZIC5 | c.1708A>T p.K570* | Nonsense Mutation (SNP) | VAF 10/118 reads (8%) | catalogued as COSV57436571; called by muse, mutect2
- ZIC5 | c.1707G>T p.R569S | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57436583; called by muse, mutect2
- ZNF160 | c.1768G>C p.E590Q | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); catalogued as COSV61998833; called by muse, mutect2, varscan2
- ZNF165 | c.1156G>C p.D386H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.226); catalogued as COSV66101910; called by muse, mutect2, varscan2
- ZNF234 | c.1063C>T p.Q355* | Nonsense Mutation (SNP) | VAF 16/88 reads (18%) | catalogued as COSV70602740; called by muse, mutect2, varscan2
- ZNF264 | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.127); catalogued as COSV54040452; called by muse, mutect2, varscan2
- ZNF292 | c.6507G>C p.L2169F | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV60535006; called by muse, mutect2, varscan2
- ZNF613 | c.1507C>T p.R503W (on ENST00000293471 / NM_001031721.4; = p.R467W on NM_024840.4) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs776131298, COSV53270697; called by mutect2, varscan2
- ZNF615 | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.438); catalogued as COSV65031905; called by muse, mutect2, varscan2
- ZNF662 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60240768; called by muse, mutect2, varscan2
- ABCC1 | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- ADAMTS16 | c.1375del p.S459Pfs*25 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel, varscan2
- ANP32B | c.534_551del p.E178_E183del | In Frame Del (DEL) | VAF 20/90 reads (22%) | called by mutect2, varscan2
- ARHGAP32 | c.3469_3472del p.S1158Gfs*13 (on ENST00000310343 / NM_001378025.1; = p.S809Gfs*13 on NM_014715.4) | Frame Shift Del (DEL) | VAF 18/92 reads (20%) | called by mutect2, pindel, varscan2
- CSRNP2 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.662); called by muse, mutect2
- URI1 | c.910G>T p.D304Y | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, varscan2
- ABCG2 | c.1209C>G p.V403= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV52942634; called by muse, mutect2, varscan2
- ACVR1C | c.222C>T p.F74= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV54643467; called by muse, mutect2, varscan2
- ADIPOQ | c.549C>T p.L183= | Silent (SNP) | VAF 11/134 reads (8%) | catalogued as COSV57858329; called by muse, mutect2
- CD9 | c.636C>T p.I212= | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as rs913329230, COSV50529873; called by muse, mutect2, varscan2
- CDC42EP3 | c.741G>A p.L247= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV54873186; called by muse, mutect2, varscan2
- CERS6 | c.705T>A p.L235= | Silent (SNP) | VAF 15/128 reads (12%) | catalogued as COSV59825940; called by muse, mutect2, varscan2
- CKAP5 | c.2997G>A p.L999= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV56363411; called by muse, mutect2, varscan2
- COL11A1 | c.81C>T p.L27= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as rs1027288806, COSV62171274; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL4A6 | c.2631G>C p.L877= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV57858271; called by muse, mutect2, varscan2
- CSGALNACT2 | c.801C>A p.I267= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV65674989; called by muse, mutect2, varscan2
- DHX57 | c.1977A>G p.L659= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as rs750133468, COSV54882123; called by muse, mutect2, varscan2
- DNAH17 | c.11898C>A p.I3966= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV67749138; called by mutect2, varscan2
- DOCK5 | c.831C>G p.L277= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV52395253; called by muse, mutect2, varscan2
- EPHA3 | c.2262C>A p.I754= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs1449076777, COSV60692350; called by muse, mutect2, varscan2
- FAM78B | c.669G>C p.L223= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV57974784; called by muse, mutect2, varscan2
- FMNL1 | c.783C>G p.L261= | Silent (SNP) | VAF 12/133 reads (9%) | catalogued as COSV58954852, COSV58960258; called by muse, mutect2
- FRMPD2 | c.1029C>T p.D343= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs764559623, COSV59714599; called by muse, mutect2, varscan2
- H4C13 | c.129C>T p.G43= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV60693025; called by muse, mutect2, varscan2
- HDAC5 | c.1479G>A p.L493= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV56816912; called by muse, mutect2
- IFI44L | c.1266G>A p.L422= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV60726449; called by muse, mutect2, varscan2
- IGHV4-34 | c.96G>A p.Q32= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs767886813; called by muse, mutect2, varscan2
- IL18RAP | c.1134T>C p.S378= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs767773927, COSV51823678; called by muse, mutect2, varscan2
- JMJD1C | c.5577C>T p.V1859= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV59512369; called by muse, mutect2, varscan2
- KCTD19 | c.744T>C p.T248= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV58570873; called by muse, mutect2, varscan2
- KIRREL3 | c.33C>T p.V11= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs1361073464, COSV68778149; called by muse, mutect2, varscan2
- LMF1 | c.1395G>C p.L465= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV51893340; called by muse, mutect2, varscan2
- MRC1 | c.2877C>T p.I959= | Silent (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- MSN | c.1137G>A p.R379= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV64303024; called by muse, mutect2
- MYBPC3 | c.1434G>A p.S478= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs770568659, COSV57022281; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYNN | c.1431G>C p.G477= | Silent (SNP) | VAF 15/128 reads (12%) | catalogued as COSV62990884; called by muse, mutect2, varscan2
- OR6C68 | c.123G>A p.L41= | Silent (SNP) | VAF 22/230 reads (10%) | catalogued as COSV65562656; called by muse, mutect2
- PDLIM7 | c.1257C>T p.F419= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs757905078, COSV63080114; called by muse, mutect2, varscan2
- PGS1 | c.1407C>G p.L469= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV53143033; called by mutect2, varscan2
- POLR3A | c.1035G>A p.L345= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV100965653, COSV64930075; called by muse, mutect2, varscan2
- R3HDM1 | c.1047G>A p.E349= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV51520467; called by muse, mutect2
- RAF1 | c.1854G>A p.R618= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV50103597; called by muse, mutect2, varscan2
- RALGAPA2 | c.1206C>T p.V402= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV52486329, COSV99173537; called by muse, mutect2
- RANBP2 | c.375C>T p.F125= | Silent (SNP) | VAF 41/372 reads (11%) | catalogued as COSV51695497; called by muse, mutect2, varscan2
- RAPSN | c.129C>T p.F43= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV54083781; called by muse, mutect2, varscan2
- RNF40 | c.474C>A p.L158= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV61213268; called by muse, mutect2
- RPL15 | c.339G>T p.L113= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV57139782; called by muse, mutect2, varscan2
- RYR3 | c.4983C>T p.L1661= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV66776027; called by muse, mutect2, varscan2
- SMARCA1 | c.2685C>A p.V895= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV64410600; called by muse, mutect2, varscan2
- SYP | c.489G>A p.G163= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs782036829, COSV54294082; called by muse, mutect2, varscan2
- TENT4B | c.1554T>C p.Y518= (on ENST00000561678 / NM_001365323.2; = p.Y503= on NM_001040284.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs767230719, COSV62546041; called by muse, mutect2
- THYN1 | c.123G>A p.Q41= | Silent (SNP) | VAF 5/87 reads (6%) | catalogued as COSV55538866; called by muse, mutect2
- TOB2 | c.327G>A p.V109= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV100548451, COSV59500273; called by muse, mutect2, varscan2
- TRAV8-6 | c.201G>A p.L67= | Silent (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2
- TRIM58 | c.849G>A p.R283= | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as COSV100825368, COSV63568907; called by muse, mutect2
- TTC23 | c.1197C>G p.A399= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV50440498; called by muse, mutect2, varscan2
- TTN | c.9075G>T p.L3025= (on ENST00000591111; = p.L2979= on NM_003319.4) | Silent (SNP) | VAF 23/153 reads (15%) | catalogued as COSV59861769; called by muse, mutect2, varscan2
- VPS52 | c.996C>T p.F332= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV71403377; called by muse, mutect2, varscan2
- XPO1 | c.522G>A p.L174= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV68944361; called by muse, mutect2, varscan2
- YAF2 | c.498T>C p.S166= | Silent (SNP) | VAF 11/130 reads (8%) | catalogued as COSV59890230; called by muse, mutect2
- ZACN | c.519C>G p.L173= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV58034461, COSV58034478; called by muse, mutect2, varscan2
- ZCCHC14 | c.1374G>C p.P458= (on ENST00000268616; = p.P595= on NM_015144.3) | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV51883213; called by mutect2, varscan2
- ZMPSTE24 | c.1038C>G p.V346= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV65638655; called by muse, mutect2, varscan2
- ZNF423 | c.2211C>T p.F737= (on ENST00000563137 / NM_001379286.1; = p.F729= on NM_015069.4) | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs138278000, COSV99283511; called by muse, mutect2, varscan2
- CCDC140 | n.782C>G | RNA (SNP) | VAF 4/20 reads (20%) | catalogued as COSV54674596; called by muse, mutect2
- DENND10P1 | n.687C>G | RNA (SNP) | VAF 17/109 reads (16%) | called by muse, mutect2, varscan2
